CCDI case PBBJGC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eebde6e1-f6ef-4772-93e5-d25d2a71c93a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.7 years (4,644 days).

Biospecimens (3 samples)
- Sample 0D9XFA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9XFB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D9XFC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
